Surgical pathology report (de-identified scan), TCGA case TCGA-26-5133, project TCGA-GBM (Glioblastoma Multiforme), tissue source site University of Florida, specimen TCGA-26-5133-01A (Primary Tumor).

[page 1 of 2]
- A. Brain tumor (b)(4)
A. Glial Fibrill. Acid Prt (b)(4)
(b)(4) 3 Protein (b)(4)
A. Neurofilament (Non-P) NF-NP (b)(4)
B. Brain tumor (b)(4)
- A. Frozen Section Charge (b)(4)
A. KI-67, Nuclear Antigen, Mib1
A. Reticulin-Gordon&Sweet (b)(4)
A. Synaptophysin (b)(4)

CLINICAL HISTORY: [REDACTED] here for right craniotomy for tumor.

GROSS DESCRIPTION: Received the following specimen in the Department of Pathology, labeled with the patient's name and hospital #:

- A. Brain tumor
B. Brain tumor

A. The specimen is received fresh labeled, "brain tumor," and consists of multiple irregular and varying sized pieces of focally hemorrhagic red-tan soft tissue measuring 3.2 x 2.2 x 0.7 cm in aggregate. A representative portion of the tissue is submitted for frozen section. Frozen section diagnosis, "malignant glioma, most likely glioblastoma," per [REDACTED] [REDACTED]. The frozen tissue is submitted for permanent processing in cassette FSA1 and additional representative portion of the tissue is submitted to the [REDACTED] tumor bank for possible future studies. The remaining tissue is entirely submitted in cassettes A2 and A3. [REDACTED]

B. The specimen is received fresh labeled, "brain tumor," and consists of multiple irregular and varying sized pieces of focally hemorrhagic beige-tan soft tissue measuring 1.6 x 1.2 x 0.5 cm in aggregate. The tissue is entirely submitted in cassette B1.

DIAGNOSIS:

- A. "Brain tumor":
Glioblastoma multiforme (WHO Grade IV astrocytoma)
- B. "Brain tumor":
Glioblastoma multiforme (WHO Grade IV astrocytoma) (see
ent)

COMMENT: This markedly pleomorphic glioma contains areas of high cellularity and brisk mitotic activity. There is vascular endothelial proliferation and focal necrosis (A2) in this material from a tumor that was ring-enhancing on MRI. Some (but not all) tumor cells are strongly immunoreactive for GFAP. The Ki-67 labeling index is quite high in areas and the tumor is strongly immunoreactive for p53 protein. Only perivascular reticulin is seen.

The presence of highly cellular foci having high proliferative rate is reminiscent of a recently described subtype of malignant glioma that contains primitive neuroectodermal tumor-like (PNET-like) components.

Reference:

1. [REDACTED] et al. Malignant gliomas with primitive neuroectodermal tumor-like components: a clinicopathologic and genetic study of 53 cases.

"I, or my qualified designee, have performed the gross examination and description and I have personally reviewed the gross description and specimen preparations referenced herein, and have personally issued this

[page 2 of 2]
report."

Resident/Prosecutor/Pathologist: [REDACTED]

Note: Test systems have been developed and their performance characteristics determined by [REDACTED] Some tests have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research: This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing. .

[REDACTED]
Pathologist

Electronically signed [REDACTED]

Source: NCI Genomic Data Commons file 7980c64a-1b78-4604-9d14-e0d3f571dcce (TCGA-26-5133.29D8F95D-E333-433B-88C6-007134D7D8A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).